Somatic mutation profile of tumor specimen HTMCP-03-06-02400-01A (aliquot HTMCP-03-06-02400-01A-01D-10409) from CGCI case HTMCP-03-06-02400, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 59.8 years (21,833 days).
Specimen HTMCP-03-06-02400-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed02cf41-d2e7-4c37-9933-cc3e4e4dd0fb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02400-10A (Blood Derived Normal), aliquot HTMCP-03-06-02400-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18528c8f-b4da-4762-9219-2df1e2b5e439

The open-access MAF lists 111 somatic variants for this specimen: 85 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 21, Intron 4, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 135/284 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs62640041, COSV61357144; called by muse, mutect2, varscan2
- ANKFN1 | c.3794G>A p.G1265E (on ENST00000653862; = p.G1118E on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.021); catalogued as rs1298356977; called by muse, mutect2, varscan2
- ARID2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57596424; called by muse, mutect2, varscan2
- ATRX | c.4541G>A p.R1514Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV64874453; called by muse, mutect2, varscan2
- ATRX | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as rs1557140475, COSV64876292; called by muse, mutect2, varscan2
- BCOR | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs767006987, COSV100654430; called by muse, mutect2, varscan2
- CARMIL3 | c.2946dup p.R983Qfs*29 | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | catalogued as rs749244991; called by mutect2, varscan2
- CCDC47 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs1476808991; called by muse, mutect2
- CREBBP | c.4405G>A p.G1469R | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD011599; called by muse, mutect2, varscan2
- DNAH11 | c.10099G>C p.E3367Q | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.92); catalogued as rs970362842; called by muse, mutect2, varscan2
- FAS | c.563_566del p.V188Gfs*120 (on ENST00000355740 / NM_001320619.2; = p.V188Gfs*2 on NM_000043.6) | Frame Shift Del (DEL) | VAF 77/135 reads (57%) | catalogued as rs1207744817; called by mutect2, pindel, varscan2
- FBN1 | c.6323G>A p.R2108H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs762659907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXL1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1310647716, COSV100206456, COSV57214573; called by muse, mutect2, varscan2
- ITGB2 | c.1903C>G p.L635V (on ENST00000302347; = p.L611V on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs774383684; called by mutect2, varscan2
- MAGI1 | c.3934G>A p.A1312T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs778933016, COSV100439589; called by muse, mutect2
- MROH2B | c.3700C>G p.L1234V | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV68182967; called by muse, mutect2, varscan2
- NCKAP5 | c.2497C>T p.L833F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); catalogued as rs969363573; called by muse, mutect2, varscan2
- NF2 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs764441073, CM941103, COSV58527597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP14 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as COSV55067191, COSV55072148; called by muse, mutect2, varscan2
- NLRP5 | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs766984450; called by muse, mutect2, varscan2
- NLRP8 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- PFKFB1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 29/170 reads (17%) | PolyPhen benign (0.039); catalogued as COSV100895837; called by muse, mutect2, varscan2
- PLCB1 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as rs1476803730; called by muse, mutect2, varscan2
- RASAL2 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs563124335; called by muse, mutect2, varscan2
- RBM6 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs768948061; called by muse, mutect2, varscan2
- RGPD8 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV56900808; called by muse, mutect2, varscan2
- SCN7A | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | catalogued as COSV69271323; called by muse, mutect2, varscan2
- SETD5 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100200756; called by muse, mutect2, varscan2
- SPTB | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs138774947; called by muse, mutect2, varscan2
- STON2 | c.1351G>A p.D451N (on ENST00000649389 / NM_001366849.2; = p.D394N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV50848934; called by muse, mutect2, varscan2
- TENM3 | c.5777C>T p.T1926M | Missense Mutation (SNP) | VAF 86/143 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs373225091; called by muse, varscan2
- THOC2 | c.3249T>A p.N1083K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99832914; called by muse, mutect2, varscan2
- TTI1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.083); catalogued as rs764958562, COSV65061632; called by muse, mutect2, varscan2
- UBE2O | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357040692; called by muse, mutect2, varscan2
- VPS16 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs750104307, COSV100988343; called by muse, mutect2, varscan2
- WDR33 | c.3653C>T p.S1218F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV100205334; called by muse, mutect2, varscan2
- ZNF519 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV73913441; called by muse, mutect2, varscan2
- ZNF681 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV101267391, COSV68075908; called by muse, mutect2, varscan2
- ADGB | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- AHCTF1 | c.2905G>A p.E969K (on ENST00000366508; = p.E943K on NM_015446.5) | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHCTF1 | c.2784G>C p.W928C (on ENST00000366508; = p.W902C on NM_015446.5) | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID4B | c.3433A>C p.K1145Q | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATRX | c.6505G>A p.G2169R | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP85 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CNST | c.630G>C p.M210I | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL4A1 | c.4507C>G p.L1503V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- COPB2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CPLANE1 | c.9218C>T p.S3073F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- DLC1 | c.2431G>A p.E811K (on ENST00000276297 / NM_001348081.2; = p.E374K on NM_006094.5) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- DLGAP4 | c.2591G>A p.C864Y (on ENST00000339266 / NM_001365621.1; = p.C861Y on NM_014902.6) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT1 | c.9555dup p.P3186Tfs*37 | Frame Shift Ins (INS) | VAF 50/116 reads (43%) | called by mutect2, pindel, varscan2
- FBN1 | c.2018del p.P673Lfs*45 | Frame Shift Del (DEL) | VAF 18/137 reads (13%) | called by mutect2, pindel, varscan2
- FREM3 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GHDC | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- GPKOW | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HEATR5A | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- HERC2 | c.9843G>C p.W3281C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HUWE1 | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- IGSF1 | c.3583G>C p.E1195Q | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- KALRN | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KDM6A | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MAP4 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP4K3 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MATK | c.851A>G p.Q284R (on ENST00000310132 / NM_139355.3; = p.Q285R on NM_002378.4) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.03); called by muse, mutect2
- MUC21 | c.434G>T p.S145I | Missense Mutation (SNP) | VAF 259/494 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MYO9A | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.438); called by muse, mutect2
- NLRC5 | c.1123T>G p.Y375D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDZD2 | c.3616G>A p.D1206N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPIL2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PSME4 | c.2347C>T p.L783F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- RALGAPA2 | c.5521G>A p.E1841K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- RNF213 | c.8874C>G p.S2958R | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RPGR | c.2776G>C p.D926H (on ENST00000339363 / NM_001367249.1; = p.D721H on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- RPS6KA6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SFSWAP | c.2303G>C p.R768T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SMARCC2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- STK11 | c.849_851dup p.D284dup | In Frame Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- THOC2 | c.3250A>T p.K1084* | Nonsense Mutation (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- THSD7A | c.2562C>A p.S854R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC39C | c.1627G>T p.V543L (on ENST00000317571 / NM_001135993.2; = p.V482L on NM_153211.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTK | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- VMP1 | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF587 | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 175/331 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF658 | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS12 | c.2589C>T p.F863= | Silent (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2
- ALPK1 | c.831C>T p.S277= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs139829354; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2781C>G p.V927= | Silent (SNP) | VAF 50/225 reads (22%) | called by muse, mutect2, varscan2
- ATP1A3 | c.1785C>T p.I595= (on ENST00000545399 / NM_001256214.2; = p.I582= on NM_152296.5) | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs781992944, COSV100132480, COSV57491495; called by muse, mutect2, varscan2
- BCOR | c.51C>T p.S17= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs771428828; called by muse, mutect2, varscan2
- CHD3 | c.1473C>T p.P491= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- CHD5 | c.5304C>T p.L1768= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV52406784; called by muse, mutect2, varscan2
- CREB5 | c.1089G>T p.G363= (on ENST00000357727 / NM_182898.4; = p.G356= on NM_004904.3) | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- DNAH8 | c.12963C>T p.F4321= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as COSV59468280; called by muse, mutect2, varscan2
- F8 | c.1767G>A p.K589= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- FLT4 | c.2442C>A p.S814= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- GUCY2F | c.1026C>T p.F342= | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as rs112671381, COSV99484592; called by muse, mutect2, varscan2
- MYH14 | c.690C>T p.V230= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- PCDHA6 | c.2112C>T p.I704= | Silent (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- RBM39 | c.300C>T p.S100= | Silent (SNP) | VAF 72/282 reads (26%) | catalogued as rs779008695, COSV53617808; called by muse, mutect2, varscan2
- RPS6KC1 | c.1290C>T p.I430= | Silent (SNP) | VAF 55/192 reads (29%) | catalogued as rs767513861, COSV65301234; called by muse, mutect2, varscan2
- SFSWAP | c.708G>A p.R236= | Silent (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- SI | c.957C>A p.G319= | Silent (SNP) | VAF 36/76 reads (47%) | called by muse, varscan2
- SPAG9 | c.1290G>A p.V430= (on ENST00000262013 / NM_001130528.3; = p.V416= on NM_003971.6) | Silent (SNP) | VAF 46/209 reads (22%) | catalogued as rs1455886749; called by muse, mutect2, varscan2
- WDR87 | c.3267C>T p.V1089= | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.552C>G p.L184= | Silent (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- GRIA1 | c.82+1260_82+1261delinsCTT | Intron (INS) | VAF 25/109 reads (23%) | called by mutect2*, pindel, varscan2*
- IGFN1 | c.1242-2485G>A | Intron (SNP) | VAF 60/332 reads (18%) | catalogued as rs550400764; called by muse, varscan2
- INTS2 | c.-2G>A | 5'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as rs750052877; called by muse, mutect2, varscan2
- MAP4 | c.1999+3149C>T | Intron (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- PML | c.1710+31C>T | Intron (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
